Gene-level copy-number profile of tumor specimen TCGA-N5-A59F-01A from TCGA case TCGA-N5-A59F, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Age at diagnosis: 65.2 years (23,826 days).
Specimen TCGA-N5-A59F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.745e5d44-a8ff-4f7f-9053-6123c9783074.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-N5-A59F-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/816b3a08-7024-4797-a4bc-3768646c6a3f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 1,981; copy number 2: 26,826; copy number 3: 17,518; copy number 4: 11,579; copy number 5: 629; copy number 6: 605; copy number 7: 180; copy number 8: 386; copy number 10: 32; copy number 11: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-N5-A59F-01A-11D-A28Q-01): tumor purity 0.72, ploidy 2.65, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:80,109,262–80,247,514, 5 genes: ADNP2, PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,907 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:81,306,147–81,992,436, 9 genes, copy number 6 (within-gene range 3–6): ADGRL2, HNRNPA3P14, ARID3BP1, AL138799.1, AL138799.3, MED28P8, AC117944.1, AL138799.2, ST13P20.
- chr1:84,574,129–85,448,124, 17 genes, copy number 5 (within-gene range 3–5): AL359762.1, AL359762.2, LINC01555, AC114482.1, SSX2IP, AC104169.1, LPAR3, MCOLN2, DNAI3, MCOLN3, MIR4423, AL603750.1, SYDE2, C1orf52, Y_RNA, BCL10, AL078459.1.
- chr2:69,457,997–70,355,915, 27 genes, copy number 5 (within-gene range 4–5): AAK1, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816, C2orf42, TIA1, MIR1285-2, RPL39P15, PCYOX1, SNRPG, FAM136A, AC022201.2, BRD7P6.
- chr2:113,058,638–116,726,771, 52 genes, copy number 5 (within-gene range 4–5): IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.2, AC010982.1, SEPHS1P7, RNU2-41P, DPP10, DPP10-AS3, DPP10-AS2, AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1.
- chr2:204,219,984–204,379,792, 3 genes, copy number 5: AC009498.1, DSTNP5, AC106901.1.
- chr3:9,986,893–10,243,745, 12 genes, copy number 5 (within-gene range 3–5): EMC3-AS1, CYCSP10, AC022007.1, CIDECP1, FANCD2, RNU6-670P, CYCSP11, FANCD2OS, BRK1, VHL, AC034193.1, IRAK2.
- chr5:2,184,710–3,601,403, 15 genes, copy number 5: Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1.
- chr5:17,684,584–35,230,487, 198 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:41,426,655–56,253,372, 234 genes, copy number 8 (broad region; genes not listed).
- chr10:103,877,374–103,879,761, 1 gene, copy number 7: AL133355.1.
- chr13:35,473,789–45,083,125, 161 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr14:22,415,362–22,469,698, 11 genes, copy number 5: AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3.
- chr15:39,588,357–39,801,333, 3 genes, copy number 6 (within-gene range 4–6): FSIP1, AC023908.2, AC023908.3.
- chr15:39,813,223–39,815,429, 1 gene, copy number 6: AC023908.1.
- chr17:65,100,812–68,422,731, 71 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr17:78,605,233–81,330,674, 90 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr18:47,390–9,254,346, 178 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:87,250–13,300,651, 274 genes, copy number 5 (broad region; genes not listed).
- chr20:44,436,172–64,313,132, 526 genes, copy number 6 (broad region; genes not listed).
- chr21:42,311,667–42,396,091, 4 genes, copy number 11: TFF3, TFF2, TFF1, TMPRSS3.
- chr21:43,529,186–44,131,181, 20 genes, copy number 5: HSF2BP, RPL31P1, H2BS1, MIR6070, RRP1B, PDXK, AP001052.1, AP001053.1, CSTB, TMEM97P1, RRP1, AATBC, MYL6P1, AGPAT3, RNU6-859P, AP001054.1, RNU6-1150P, TRAPPC10, H2AZP1, PWP2.

Autosomal genes at a single copy (total copy number 1): 471. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
